Somatic mutation profile of tumor specimen 0DKO7N from CCDI case PBBYJD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.3 years (3,393 days).
Specimen 0DKO7N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97a898e3-c286-45eb-81c8-3b0e117cec7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKO75 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24b8f8fb-e023-457d-ad9b-ad747c691f67

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERV3-1 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 246/1150 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs371937339; called by muse, mutect2, varscan2
- PHF19 | c.66C>A p.N22K | Missense Mutation (SNP) | VAF 62/568 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1487734169; called by muse, mutect2, varscan2
- ST6GAL1 | c.50T>G p.F17C | Missense Mutation (SNP) | VAF 64/1943 reads (3%) | PolyPhen possibly damaging (0.818); catalogued as COSV99398574; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 41/1722 reads (2%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DENND4A | c.3776C>T p.P1259L | Missense Mutation (SNP) | VAF 52/1425 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2
